TARGET case TARGET-20-PARNXZ — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/d01af346-f6d7-4963-813a-521f114c0a18

Biospecimens (2 samples)
- Sample TARGET-20-PARNXZ-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-20-PARNXZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
